Surgical pathology report (de-identified scan), TCGA case TCGA-06-0397, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0397-01A (Primary Tumor).

[page 1 of 5]
Patient Name: MRN: Sex: Female Room/Bed:

PATIENT NAME: AGE/SEX: F ACC. NO. UUID: 288D4FB8-8D9D-4E16-BDC9-B1C69CEF0452
HOSP. NO. TCGA-06-0397-01A-PR Redacted
ORDERING PHYSICIAN:

PATH. NO:

NAME: MED. REC.

COLLECT DATE:

PHYSICIAN:

PATHOLOGICAL DIAGNOSIS:

- A) BRAIN, SITE UNSPECIFIED, BIOPSY: GLIOBLASTOMA.
B) BRAIN, SITE UNSPECIFIED, BIOPSY: CEREBRAL CORTEX AND WHITE
MATTER, NEGATIVE FOR TUMOR.
C) BRAIN, SITE UNSPECIFIED, RESECTION: GLIOBLASTOMA.
-

Operation/Specimen: Brain lesion.

Clinical History and Pre-Op Dx: None provided.

GROSS PATHOLOGY: A. The specimen labeled "brain lesion", was submitted for frozen section diagnosis.

INTRAOPERATIVE CONSULTATION, Frozen section diagnosis: Glioblastoma.

. The specimen consists of three fragments of soft, moist light tan to yellow tissue, the larger measuring approximately 1.4 cm. in diameter. Small fragment of the tissue is fixed in gluteraldehyde for possible Electronmicroscopy. The remaining tissue for the frozen section block is submitted for KI-67 monoclonal antibody staining and the entire specimen is submitted in one cassette designated 1.

B. Is received unfixed designated "normal brain", consists of a fragment of grossly identifiable cerebral tissue measuring 2.3 x 1.4 x 1 cm. The cortex and white matter are grossly recognized. Entirely submitted in two cassettes after being bisected. Cassettes 2&3.

C. Is received unfixed designated "brain tumor", and consists of three irregular and hemorrhagic fragment of tissue measuring approximately 3.5 x 2.5 x 2 cm. The fragments are partially covered by grossly identifiable cerebral cortex with pronounced meningeal congestion. Entire specimen is submitted in three cassettes designated 4,5&6.

MICROSCOPIC: A,C. These two specimens show a high grade glial neoplasm characterized by a densely cellular proliferation of atypical glial cells with ill-defined cell boundaries, high nuclera/cytoplasmic ratio, pleomorphic nuclei and frequent mitoses. A vague perivascular arrangement of fine fibrils is occasionally present. Stromal vessels show endothelial hyperplasia. Small and confluent areas of necrosis are present within the tumor, in some cases with nuclear palisades. Specimen C also consists of fragments of uninvolved cerebral cortex and white matter.

Performed.

Stain with Ki-67 monoclonal antibody is pending. Additional report will follow.

[page 2 of 5]
Patient Name:

MRN:

Sex: Female Room/Bed:

SPECIAL STAINS:.

ADDENDUM

Stain with monoclonal antibody Ki-G7 on frozen sections of the tumor reveals a proliferating index of approximately 12%, in keeping with published Ki-67 proliferation index for glioblastomas. Stain with monoclonal antibody Mib-1 in paraffin sections of block #1, also reveal a high proliferation index,

Requested by:

[page 3 of 5]
Patient Name:

MRN:

Birth Date:

Sex: Female Room/Bed:

estimated at approximately 16%-18%.

[page 4 of 5]
Patient Name:

M. MRN

Birth Date:

S. female Room/Bed:

PATIENT NAME:

HOSP. NO.:

AGE/SEX:

ACC. NO.:

PATH. NO:

NAME:

MED. REC. NO:

AGE/SEX: F

PHYSICIAN

PATHOLOGICAL DIAGNOSIS:LEFT PARIETAL BIOPSY: GLIOBLASTOMA MULTIFORME WITH LEPTOMENINGEAL
EXTENSION

Operation/Specimen: L. parietal brain tumor.

Clinical History and Pre-Op Dx: Glioblastoma.

GROSS PATHOLOGY: The specimen is labeled "left parietal brain tumor", are several fragments of pink-red to gray soft tissue. A portion of the specimen has been examined for frozen section and is submitted in cassettes 1 and 2 with the brain tissue in cassettes 3 and 4.

INTRAOPERATIVE CONSULTATION, Frozen section diagnosis: Glioblastoma.

MICROSCOPIC: Sections reveal a glioblastoma multiforme with large areas of tumor necrosis. In the hypercellular areas, nuclear pleomorphism is frequent. However, mitotic figures are rare. The tumor extends into the subarachnoid space and markedly expands the sulci.

SPECIAL STAINS:.

BILLING CODES:

[page 5 of 5]
Patient Name:

MRN

Birth Date:

Sex: Room/Bed:

ADDENDUM

RESULT OF IMMUNOSTAIN

MICRO: Immunostain on slide 4 shows strong positivity of the tumor cells for glial fibrillary acid protein. This finding is in keeping with the astrocytic nature of the tumor cells. There is no change of the diagnosis of this case: Glioblastoma multiforme.

Source: NCI Genomic Data Commons file 10acba52-2f52-4360-9ded-18011ff2b381 (TCGA-06-0397.288D4FB8-8D9D-4E16-BDC9-B1C69CEF0452.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).